Somatic mutation profile of tumor specimen MP2PRT-PAPFWC-TMP1-A (aliquot MP2PRT-PAPFWC-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PAPFWC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.4 years (2,716 days).
Specimen MP2PRT-PAPFWC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c852492f-490c-4fcf-99f6-7dabff586802.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPFWC-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPFWC-NM1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bd9df38a-ba7c-4dd1-acad-e2ed18be8cbb

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 8, Silent 5, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FNDC1 | c.607C>T p.R203W | Missense Mutation (SNP) | VAF 55/279 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201087585; called by muse, mutect2, varscan2
- KRT33A | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 128/428 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs754250148, COSV50367446; called by muse, varscan2
- NAA25 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as rs752979488; called by muse, mutect2, varscan2
- SLC19A3 | c.494C>T p.A165V | Missense Mutation (SNP) | VAF 118/334 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as rs144223086, COSV99295779; called by muse, varscan2
- FMN1 | c.2951C>A p.P984H (on ENST00000616417 / NM_001277313.2; = p.P761H on NM_001103184.4) | Missense Mutation (SNP) | VAF 40/122 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- HHIPL2 | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 34/273 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.849); called by muse, varscan2
- KRTAP1-5 | c.332_378del p.A111Gfs*45 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2*, pindel
- MON1B | c.259T>A p.C87S | Missense Mutation (SNP) | VAF 99/348 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRTG | c.2348A>C p.Q783P | Missense Mutation (SNP) | VAF 68/202 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, varscan2
- CATSPERG | c.2862G>A p.G954= | Silent (SNP) | VAF 152/412 reads (37%) | called by muse, varscan2
- COL4A1 | c.1365C>T p.G455= | Silent (SNP) | VAF 90/262 reads (34%) | catalogued as rs576636085; called by muse, varscan2
- GPR78 | c.270G>A p.A90= | Silent (SNP) | VAF 167/495 reads (34%) | called by muse, mutect2, varscan2
- LGALS2 | c.336C>T p.S112= | Silent (SNP) | VAF 112/325 reads (34%) | called by muse, varscan2
- NES | c.2373T>G p.L791= | Silent (SNP) | VAF 67/332 reads (20%) | called by muse, varscan2
